Somatic mutation profile of tumor specimen MMRF_2788_1_BM_CD138pos (aliquot MMRF_2788_1_BM_CD138pos_T1_KHS5U_L15731) from MMRF case MMRF_2788, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2788_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 082d0791-2348-4a04-b2f6-4d0ee4ad34bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2788_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2788_1_PB_WBC_C3_KHS5U_L15775; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47dc14de-e003-4269-9de6-e0547f4ebf30

The open-access MAF lists 106 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 19, Silent 16, 5'UTR 11, Intron 11, 5'Flank 7, 3'Flank 4, Nonsense Mutation 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 45/73 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGAP1 | c.2047G>A p.E683K (on ENST00000304032 / NM_001037131.3; = p.E630K on NM_014914.5) | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.909); catalogued as rs563206172; called by muse, mutect2, varscan2
- COL22A1 | c.4675G>A p.G1559R | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207127046, COSV100280108; called by muse, mutect2, varscan2
- EYS | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV60976589; called by muse, mutect2, varscan2
- IGHV1-69 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 120/299 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as rs782325637; called by muse, mutect2, varscan2
- IGHV2-70D | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1171315859; called by muse, varscan2
- IGLL5 | c.181T>C p.S61P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs939720182; called by muse, mutect2, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, varscan2
- IGLV3-1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs368499668; called by muse, varscan2
- IGLV3-1 | c.345C>G p.H115Q | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.606); catalogued as rs778942547; called by muse, varscan2
- MICAL3 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 48/101 reads (48%) | catalogued as COSV52892627; called by muse, mutect2, varscan2
- TBC1D4 | c.14G>C p.S5T | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.827); catalogued as rs776733868, COSV66492737; called by muse, mutect2, varscan2
- TYR | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as CM033064, CM135761, COSV54484751; called by muse, mutect2, varscan2
- CBFB | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCNB3 | c.3038T>G p.I1013R | Missense Mutation (SNP) | VAF 88/95 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CTNNA2 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DHFR2 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EPHA6 | c.2562C>G p.D854E (on ENST00000389672 / NM_001080448.3; = p.D246E on NM_173655.4) | Missense Mutation (SNP) | VAF 74/168 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXOSC3 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM177A1 | c.247G>C p.D83H (on ENST00000382406 / NM_001289022.2; = p.D106H on NM_173607.5) | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FANCM | c.2506T>A p.C836S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FAT2 | c.281dup p.L95Pfs*49 | Frame Shift Ins (INS) | VAF 101/273 reads (37%) | called by mutect2, pindel, varscan2
- GTF3C1 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- H2BC13 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HNRNPF | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2
- HTR2C | c.836A>C p.N279T | Missense Mutation (SNP) | VAF 113/141 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PCARE | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PDE7B | c.1325G>A p.S442N | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU6F2 | c.1242A>C p.Q414H | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RNASE4 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.303); called by muse, mutect2
- RYR3 | c.12292G>C p.A4098P (on ENST00000389232; = p.A4099P on NM_001036.6) | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA7 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- SPTAN1 | c.2299G>C p.E767Q | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- STAG2 | c.2742G>C p.Q914H | Missense Mutation (SNP) | VAF 30/35 reads (86%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- XCR1 | c.1000T>C p.*334Rext*81 | Nonstop Mutation (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- ZCCHC7 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZNF69 | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 202/518 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF710 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRE1 | c.258A>G p.Q86= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, mutect2, varscan2
- ANKRD52 | c.54C>T p.S18= | Silent (SNP) | VAF 112/242 reads (46%) | called by muse, mutect2, varscan2
- AP3M1 | c.681T>A p.L227= | Silent (SNP) | VAF 64/145 reads (44%) | called by muse, mutect2, varscan2
- ARAP3 | c.3402C>T p.V1134= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99499783; called by muse, mutect2, varscan2
- CBLN2 | c.288C>T p.S96= | Silent (SNP) | VAF 89/201 reads (44%) | catalogued as rs1009937847; called by muse, mutect2, varscan2
- FRMD7 | c.1425C>T p.Y475= | Silent (SNP) | VAF 119/141 reads (84%) | catalogued as rs766736966; called by muse, mutect2, varscan2
- H4-16 | c.174C>T p.V58= | Silent (SNP) | VAF 58/170 reads (34%) | catalogued as rs566622753; called by muse, mutect2, varscan2
- IGHV3-23 | c.288C>T p.N96= | Silent (SNP) | VAF 184/581 reads (32%) | catalogued as rs782746491; called by muse, mutect2, varscan2
- INO80 | c.2032T>C p.L678= | Silent (SNP) | VAF 84/195 reads (43%) | called by muse, varscan2
- MGAM2 | c.987C>A p.P329= | Silent (SNP) | VAF 115/235 reads (49%) | called by muse, mutect2, varscan2
- OR5AP2 | c.255C>A p.P85= | Silent (SNP) | VAF 122/251 reads (49%) | called by muse, mutect2, varscan2
- OTOGL | c.5730G>A p.T1910= (on ENST00000547103; = p.T1901= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 79/203 reads (39%) | catalogued as rs762557747, COSV100087576, COSV54020253; called by muse, mutect2, varscan2
- RNF150 | c.570A>C p.T190= | Silent (SNP) | VAF 147/350 reads (42%) | called by muse, mutect2, varscan2
- SBK2 | c.657G>A p.P219= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as rs918486029; called by muse, mutect2, varscan2
- ST8SIA3 | c.210G>A p.P70= | Silent (SNP) | VAF 98/213 reads (46%) | catalogued as rs987810090, COSV100129770; called by muse, mutect2, varscan2
- TNXB | c.8889A>G p.A2963= (on ENST00000647633; = p.A2716= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- ACTN1 | c.-179_-171dup | 5'UTR (INS) | VAF 18/63 reads (29%) | called by mutect2, varscan2
- AP001993.1 | chr11:127100115 G>A | 3'Flank (SNP) | VAF 19/43 reads (44%) | catalogued as rs992083253; called by muse, mutect2, varscan2
- ATP8B4 | c.*452A>T | 3'UTR (SNP) | VAF 33/82 reads (40%) | catalogued as rs1327017094; called by muse, mutect2, varscan2
- ATP9A | c.*4596C>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs576416544, COSV58764739; called by muse, mutect2, varscan2
- BCL7A | chr12:122021578 G>A | 5'Flank (SNP) | VAF 71/150 reads (47%) | catalogued as rs570032179, COSV55849579; called by muse, mutect2, varscan2
- BMP5 | c.-558A>G | 5'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- CCND1 | c.-4A>G | 5'UTR (SNP) | VAF 15/43 reads (35%) | catalogued as rs1379943115; called by muse, mutect2, varscan2
- CLNK | c.*427T>C | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- CTSC | c.319-10172A>T | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- DCC | c.*142A>G | 3'UTR (SNP) | VAF 80/173 reads (46%) | catalogued as COSV71442655; called by muse, mutect2, varscan2
- DMD | c.*1182C>T | 3'UTR (SNP) | VAF 36/44 reads (82%) | catalogued as rs187318961; called by muse, mutect2, varscan2
- DPYSL5 | c.*2250G>T | 3'UTR (SNP) | VAF 79/203 reads (39%) | called by muse, mutect2, varscan2
- DTNA | c.1662+3729G>C | Intron (SNP) | VAF 35/225 reads (16%) | called by muse, mutect2, varscan2
- DTX1 | c.-445G>T | 5'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- FGF11 | c.*783C>T | 3'UTR (SNP) | VAF 67/167 reads (40%) | called by muse, mutect2, varscan2
- FIBIN | c.*1078C>G | 3'UTR (SNP) | VAF 32/81 reads (40%) | catalogued as rs995966437; called by muse, mutect2, varscan2
- GDF9 | c.*330G>C | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155067286 C>T | 5'Flank (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- IGSF9B | chr11:133956826 G>T | 5'Flank (SNP) | VAF 56/137 reads (41%) | catalogued as rs375569334; called by muse, mutect2, varscan2
- IKZF3 | c.-59_-54del | 5'UTR (DEL) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- IRF2BPL | c.*352T>C | 3'UTR (SNP) | VAF 25/64 reads (39%) | catalogued as rs1481447519; called by muse, mutect2, varscan2
- IRF2BPL | c.*160T>A | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- ISM1 | c.*485T>G | 3'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+956A>C | Intron (SNP) | VAF 82/196 reads (42%) | called by muse, mutect2, varscan2
- KLHL8 | c.*1670dup | 3'UTR (INS) | VAF 38/84 reads (45%) | catalogued as rs1400264817; called by mutect2, varscan2
- LTB | c.163-145G>A | Intron (SNP) | VAF 84/221 reads (38%) | catalogued as rs140984421, COSV53000853; called by muse, varscan2
- LUC7L3 | chr17:50754042 T>G | 3'Flank (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- MIR5195 | chr14:106851275 T>A | 5'Flank (SNP) | VAF 124/286 reads (43%) | catalogued as rs542998783; called by muse, mutect2, varscan2
- MTMR7 | c.-34C>T | 5'UTR (SNP) | VAF 8/56 reads (14%) | catalogued as rs1411861341; called by muse, mutect2, varscan2
- MYO1E | c.-108T>G | 5'UTR (SNP) | VAF 64/164 reads (39%) | called by muse, varscan2
- MYO1E | c.-211G>C | 5'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, varscan2
- NETO1 | c.469+23927T>C | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, varscan2
- ONECUT2 | c.*2016A>G | 3'UTR (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- OXSM | chr3:25789925 C>G | 5'Flank (SNP) | VAF 77/183 reads (42%) | catalogued as COSV99772000; called by muse, mutect2, varscan2
- PDLIM2 | c.-22G>A | 5'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- PLLP | chr16:57253645 T>C | 3'Flank (SNP) | VAF 10/28 reads (36%) | called by muse, varscan2
- PPARGC1A | c.877+3655T>G | Intron (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-677G>T | Intron (SNP) | VAF 18/209 reads (9%) | catalogued as rs749037280; called by muse, mutect2
- PRR5L | c.*1620T>A | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- PTEN | c.-69A>C | 5'UTR (SNP) | VAF 100/227 reads (44%) | called by muse, mutect2, varscan2
- RPRD2 | chr1:150474626 T>A | 3'Flank (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- SMG7 | c.-53G>C | 5'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, varscan2
- SNRK | c.*1576T>C | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- TMEM250 | c.*1863C>T | 3'UTR (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975326 T>A | 5'Flank (SNP) | VAF 75/88 reads (85%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975590 C>G | 5'Flank (SNP) | VAF 155/178 reads (87%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TNKS | c.673+817T>C | Intron (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- TPO | c.482+2446A>G | Intron (SNP) | VAF 190/415 reads (46%) | called by muse, mutect2, varscan2
- TTLL9 | c.1243+172G>A | Intron (SNP) | VAF 17/31 reads (55%) | called by muse, varscan2
- YAP1 | c.*1266C>A | 3'UTR (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2
- ZNF621 | c.*2247G>A | 3'UTR (SNP) | VAF 78/190 reads (41%) | called by muse, mutect2, varscan2
- ZNF680 | c.254-2709C>T | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as rs900715205; called by muse, mutect2, varscan2
